Surgical pathology report (de-identified scan), TCGA case TCGA-44-7669, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-7669-01A (Primary Tumor).

[page 1 of 5]
DEPARTMENT OF PATHOLOGY AND LABORATORY MEDICINE

Date Coll:

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Right upper lobe
- B. Level 10 lymph node
- C. Level 3 lymph node
- D. Level 4 lymph node
- E. Level 7 lymph node

FROZEN SECTION DIAGNOSIS

FSC) Level 3 lymph node - Negative for malignancy.

FSD) Level 4 lymph node - Negative for malignancy.

FSE) Level 7 lymph node - Negative for malignancy.

[page 2 of 5]
GROSS DESCRIPTION

A. Submitted fresh labelled "right upper lobe." It consists of a lobe of lung tissue submitted for tissue procurement. Lobe has a large perihilar lymph node present which appears to have encased the bronchus at the point of resection. This node, on cut section is 2.5 cm in greatest extent and has a mottled tan and black cut surface. There is an area of pleural thickening and puckering on the apical portion of the lobectomy. Serial sections taken through the lung reveal a large discrete circumscribed tumor in the apex measuring 2.3 x 1.9 x 1.5 cm. It too has a granular tan and black cut surface appearance and is sharply demarcated from the surrounding lung. It approaches the visceral pleural surface but does not appear to involve it. Adjacent to tumor there is an area of discoloration and thickening of the lung parenchyma as well as some apparent emphysematous changes in the more distal parenchyma. Portion of tumor and normal tissue submitted for tissue procurement per request of the surgeon.

BLOCK SUMMARY: 1 - bronchial margin; 2 - positive hilar lymph node with encased bronchus; 3- hilar node; 4 - positive hilar lymph node and second lymph node; 5-8 - tumor; 9 - additional lung section.

[page 3 of 5]
B. Submitted 10% formalin labelled "level 10 lymph node" is a 1.5 cm aggregate of anthracotic soft tissue.

C. Submitted fresh for frozen labelled "level 3 lymph node" is a 1 cm nodule of anthracotic lymph node tissue submitted entirely for frozen section.

D. Submitted fresh for frozen labelled "level 4 lymph node" is a 1.7 cm aggregate of soft anthracotic tissue submitted entirely for frozen section.

E. Submitted fresh for frozen section labelled "level 7 lymph node" is a 2.5 cm aggregate of anthracotic soft tissue submitted entirely for frozen section.

MICROSCOPIC DESCRIPTION

Microscopic sections of the lung carcinoma reveals a poorly differentiated non-small cell carcinoma. The tumor is growing in discrete nodules and packets filling the air spaces with somewhat columnar cells with a peripheral picket-fence-like pattern of growth. Individual cells are hyperchromatic with frequent mitotic activity. The tumor is negative for mucicarmine. It does show strong positivity for TTF-1 and CEA and is negative for P63. This

[page 4 of 5]
[REDACTED]
[REDACTED]
[REDACTED]

indicates that it is a poorly differentiated adenocarcinoma.

Results of the resection are summarized in the following template.

Histologic type: Adenocarcinoma.

Histologic grade: Poorly differentiated.

Primary tumor (pT): Tumor is 2.3 cm in size and not involve the visceral pleural surface (pT1b).

Margins of resection: Negative.

Direct extension of tumor: Absent.

Venous (large vessel) invasion: Present.

Arterial (large vessel) invasion: Negative.

Lymphatic (small vessel) invasion: Small vessel invasion present.

Regional lymph nodes (pN): 1 of 2 hilar lymph nodes contains metastatic carcinoma. All sampled mediastinal lymph nodes are negative for tumor (pN1).

Distant metastasis (pM): pMX.

Other findings: Focal infarction distal to the tumor.

Emphysematous changes.

[REDACTED]

[page 5 of 5]
[REDACTED]
[REDACTED]
[REDACTED]

DIAGNOSIS

A. Lung, right upper lobectomy:

Invasive poorly differentiated adenocarcinoma.

Tumor is confined to the lung and does not involve the visceral pleural surface.

One of two peribronchial lymph nodes is positive for metastatic carcinoma (1/2).

Large venous vessel and lymphatic vessel invasion by tumor is present. Emphysematous changes.

Focal distal infarction.

B. Lymph node, level 10, resection:

Negative for malignancy.

C. Lymph node, level 3, resection:

Negative for malignancy.

D. Lymph node, level 4, resection:

Negative for malignancy.

E. Level 7, resection:

Negative for malignancy.

[REDACTED]

----- [REDACTED]

[REDACTED] (Electronic Signature)

--- End Of Report ---

Source: NCI Genomic Data Commons file ecd516e0-534d-45f5-ac25-14a336ddd04e (TCGA-44-7669.4B112ED4-A999-467D-AACE-8BC2C13DB1CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).